MMRF case MMRF_2166 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5f144a52-05f1-4b60-b592-d818c006143d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 88 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 88.1 years (32,196 days); ISS stage: II; Days to last known disease status: 26 days; Days to last follow up: 26 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 12 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 17 days; Days to treatment end: 28 days.

Follow-up (2 entries)
- Days to follow up: 14 days; ECOG performance status: 2.
- Follow-up contact recording only the day: day 26.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Leukocytes 8.4 ×10⁹/L.
- Platelets 209 ×10⁹/L.
- M Protein 1.98 g/dL.
- Albumin 28 g/L.
- Calcium 2.2 mmol/L.
- Absolute Neutrophil 6.3 ×10⁹/L.
- Glucose 7.65 mmol/L.
- Blood Urea Nitrogen 6.07 mmol/L.
- Hemoglobin 8.56 mmol/L.
- Creatinine 88.4 µmol/L.
- Total Protein 7.6 g/dL.
- Beta 2 Microglobulin 0.23 µg/mL.

Other clinical attributes
- Day 14: Weight: 77 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2166_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 14 days.
- Sample MMRF_2166_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 14 days.
